Somatic mutation profile of tumor specimen 8234f8ea-bdbd-45b0-bd0b-16f1e7 (aliquot 8234f8ea-bdbd-45b0-bd0b-16f1e7_D6) from CPTAC case 17OV030, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB.
Specimen 8234f8ea-bdbd-45b0-bd0b-16f1e7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dacc81ad-5c72-467c-b1db-1c12d2909dd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ef0d574a-0abb-4e12-bef4-c01511 (Blood Derived Normal), aliquot ef0d574a-0abb-4e12-bef4-c01511_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d16d1df-13e7-420f-acb0-efb3760ced55

The open-access MAF lists 122 somatic variants for this specimen: 75 protein-altering or splice-affecting, 28 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 28, Intron 10, 5'UTR 3, Splice Site 3, In Frame Del 3, Nonsense Mutation 2, RNA 2, 3'Flank 2, 5'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 139/270 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.3173C>T p.S1058L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs767490706, COSV52368057; called by muse, mutect2, varscan2
- AKT2 | c.157A>T p.N53Y | Missense Mutation (SNP) | VAF 94/514 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60908123; called by mutect2, varscan2
- ARMC5 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 111/603 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as rs1273492014; called by muse, mutect2, varscan2
- DCUN1D4 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV58121487; called by muse, mutect2, varscan2
- GPATCH2L | c.668C>G p.T223S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.987); catalogued as COSV55047194; called by muse, mutect2, varscan2
- H3C2 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV52518637, COSV52519594, COSV99451261; called by muse, mutect2
- IGHA2 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 78/782 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); catalogued as rs782203806; called by muse, mutect2
- KDM6B | c.3264C>A p.D1088E | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as rs763954139; called by muse, mutect2, varscan2
- KPRP | c.830C>G p.P277R | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs752162119; called by muse, mutect2, varscan2
- LGALS13 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1272808677, COSV99694883; called by muse, mutect2, varscan2
- OBSL1 | c.4610C>T p.P1537L | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1438740649; called by muse, mutect2, varscan2
- PLXNB3 | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); catalogued as rs782508777, COSV62797617; called by muse, mutect2, varscan2
- POLM | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV54244093; called by muse, mutect2, varscan2
- RAB42 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.05); catalogued as rs530073440, COSV65753155; called by muse, mutect2, varscan2
- RYR2 | c.6977G>A p.R2326Q | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773565555, COSV63685479; called by muse, mutect2, varscan2
- SLC25A11 | c.20C>G p.A7G | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); catalogued as COSV99337410; called by muse, mutect2, varscan2
- SUMF1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 86/403 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139267495; called by muse, varscan2
- SV2B | c.1869-2A>G p.X623_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | catalogued as rs1199458511, COSV57699340; called by muse, mutect2, varscan2
- SYT12 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 60/299 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.025); catalogued as rs1220363169; called by muse, mutect2, varscan2
- TSPEAR | c.1084G>C p.V362L | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.334); catalogued as COSV59959310, COSV59961665; called by muse, mutect2, varscan2
- TTN | c.102785C>T p.P34262L (on ENST00000591111; = p.P26838L on NM_003319.4) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | PolyPhen benign (0.027); catalogued as COSV100636335; called by muse, mutect2, varscan2
- ARX | c.662C>A p.T221N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, varscan2
- ATP7A | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- CACNA1A | c.6083G>C p.S2028T | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CALR | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- CANT1 | c.974_1024del p.P325_T341del | In Frame Del (DEL) | VAF 58/298 reads (19%) | called by mutect2, pindel
- CD300E | c.591G>T p.R197S | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP89 | c.1146G>C p.E382D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP46 | c.6041C>G p.S2014C | Missense Mutation (SNP) | VAF 75/389 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CFAP46 | c.5691_5712del p.E1898Cfs*22 | Frame Shift Del (DEL) | VAF 38/187 reads (20%) | called by mutect2, pindel, varscan2
- CLCNKA | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CMIP | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- COPE | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CPE | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPG4 | c.3223A>T p.T1075S | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- EML5 | c.4634G>C p.R1545T (on ENST00000380664; = p.R1553T on NM_183387.3) | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- EPHA3 | c.1632G>A p.M544I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- FAM8A1 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FOXD4L3 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 102/607 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABBR1 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- HERC1 | c.13099G>C p.A4367P | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HSD17B4 | c.425-1G>T p.X142_splice (on ENST00000414835 / NM_001199291.3; = p.X117_splice on NM_000414.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 23/96 reads (24%) | called by mutect2, varscan2
- KRBA1 | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LCE1A | c.179G>C p.C60S | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT tolerated, low confidence (0.61); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LIMA1 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MAOA | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MC3R | c.885C>G p.D295E | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MDN1 | c.3756T>A p.D1252E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2
- MICAL3 | c.3736C>A p.P1246T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC12 | c.7850C>T p.T2617I (on ENST00000379442; = p.T2474I on NM_001164462.1) | Missense Mutation (SNP) | VAF 58/1626 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2
- NT5E | c.1326C>G p.Y442* | Nonsense Mutation (SNP) | VAF 105/438 reads (24%) | called by muse, mutect2, varscan2
- OR8J3 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- PCDHGB6 | c.11G>C p.S4T | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PKD1 | c.3871G>A p.V1291I | Missense Mutation (SNP) | VAF 206/760 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- PLCB4 | c.1626_1648delinsGT p.E543_A550delinsS | In Frame Del (DEL) | VAF 18/108 reads (17%) | called by pindel, varscan2*
- POLD4 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PPP1R26 | c.942G>C p.E314D | Missense Mutation (SNP) | VAF 132/267 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- RAB34 | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 76/123 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- RALGAPA1 | c.1809G>C p.Q603H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- RASGRF1 | c.1481T>A p.L494Q | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS26 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SEL1L3 | c.3084-14_3090del p.X1028_splice | Splice Site (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- SLC5A10 | c.1374_1388del p.V459_F463del (on ENST00000395645 / NM_001042450.4; = p.V475_F479del on NM_152351.5) | In Frame Del (DEL) | VAF 55/214 reads (26%) | called by mutect2, pindel, varscan2
- STAB2 | c.1038T>A p.T346= | Splice Region (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- TDRKH | c.1026G>C p.Q342H | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TTC7B | c.1778A>C p.Q593P | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TTN | c.99687T>A p.D33229E (on ENST00000591111; = p.D25805E on NM_003319.4) | Missense Mutation (SNP) | VAF 64/327 reads (20%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- UBTF | c.618G>A p.W206* | Nonsense Mutation (SNP) | VAF 72/278 reads (26%) | called by muse, mutect2, varscan2
- VCPIP1 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); called by muse, mutect2
- VEGFD | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WASF2 | c.842A>G p.Q281R | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- WASHC2A | c.2789T>C p.I930T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY4 | c.3214T>A p.F1072I | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by mutect2, varscan2
- WIZ | c.4881G>C p.K1627N (on ENST00000673675 / NM_001371589.1; = p.K532N on NM_021241.3) | Missense Mutation (SNP) | VAF 98/513 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- AFAP1L1 | c.462T>C p.I154= | Silent (SNP) | VAF 30/187 reads (16%) | called by muse, mutect2, varscan2
- CASS4 | c.873T>A p.T291= | Silent (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- CNKSR1 | c.555G>C p.L185= | Silent (SNP) | VAF 108/474 reads (23%) | catalogued as rs754507482; called by muse, mutect2, varscan2
- DDB1 | c.2217C>T p.R739= | Silent (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- GALNT13 | c.495A>T p.T165= | Silent (SNP) | VAF 30/113 reads (27%) | called by muse, mutect2, varscan2
- GGNBP2 | c.597G>C p.S199= | Silent (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- GREB1L | c.3957A>G p.T1319= | Silent (SNP) | VAF 32/180 reads (18%) | called by muse, mutect2, varscan2
- H2AC21 | c.39T>C p.A13= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs1278118495, COSV58611635; called by mutect2, varscan2
- MAGEB4 | c.888C>A p.T296= | Silent (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- MAST1 | c.480G>A p.R160= | Silent (SNP) | VAF 31/193 reads (16%) | catalogued as rs1277836656, COSV52253928; called by muse, mutect2, varscan2
- MINDY1 | c.1137G>T p.G379= | Silent (SNP) | VAF 22/163 reads (13%) | called by muse, mutect2, varscan2
- MINDY4B | c.996C>G p.T332= | Silent (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- MYH6 | c.3672C>T p.S1224= | Silent (SNP) | VAF 99/908 reads (11%) | catalogued as rs755267212; called by muse, varscan2
- OPRK1 | c.522G>A p.K174= | Silent (SNP) | VAF 85/244 reads (35%) | catalogued as COSV55572833; called by muse, mutect2, varscan2
- PARP12 | c.411T>C p.Y137= | Silent (SNP) | VAF 48/135 reads (36%) | called by muse, mutect2, varscan2
- PCDH9 | c.714G>T p.L238= | Silent (SNP) | VAF 56/226 reads (25%) | called by mutect2, varscan2
- PIEZO1 | c.261G>A p.L87= | Silent (SNP) | VAF 41/154 reads (27%) | called by muse, mutect2, varscan2
- PKD1 | c.3870G>C p.L1290= | Silent (SNP) | VAF 209/759 reads (28%) | called by muse, mutect2, varscan2
- PRKDC | c.4062A>G p.E1354= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- RAB3B | c.585G>A p.P195= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as rs780152564, COSV100862455; called by muse, mutect2, varscan2
- RSPH4A | c.1425T>A p.P475= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV99994349; called by muse, mutect2, varscan2
- SLC5A9 | c.247C>T p.L83= | Silent (SNP) | VAF 83/260 reads (32%) | called by muse, mutect2, varscan2
- STIM2 | c.1563G>A p.P521= | Silent (SNP) | VAF 78/354 reads (22%) | catalogued as rs148146721, COSV52840719; called by mutect2, varscan2
- TMEM143 | c.399G>A p.R133= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs369405370; called by muse, mutect2, varscan2
- TMEM87B | c.972C>T p.I324= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs547196638, COSV51715279; called by mutect2, varscan2
- UGT2B28 | c.45T>A p.G15= | Silent (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- UQCC2 | c.21G>A p.R7= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV65268791; called by muse, mutect2, varscan2
- ZNF518A | c.4122A>T p.V1374= | Silent (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- AIPL1 | c.466-12C>G | Intron (SNP) | VAF 82/285 reads (29%) | called by muse, mutect2, varscan2
- ASPG | c.192-16T>C | Intron (SNP) | VAF 68/356 reads (19%) | called by muse, mutect2, varscan2
- ATG2A | chr11:64891324 G>A | 3'Flank (SNP) | VAF 146/463 reads (32%) | called by muse, mutect2, varscan2
- C1QTNF6 | c.289+859C>G | Intron (SNP) | VAF 55/245 reads (22%) | called by muse, mutect2, varscan2
- CEMIP | c.-3A>C | 5'UTR (SNP) | VAF 87/574 reads (15%) | called by muse, mutect2, varscan2
- CLEC4A | c.299-1036G>A | Intron (SNP) | VAF 58/270 reads (21%) | called by muse, mutect2, varscan2
- GMFB | c.4-229T>G | Intron (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- HTR2B | c.-45G>C | 5'UTR (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- IPO7 | c.84+7413C>T | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as rs1322053798; called by muse, mutect2
- JMJD7-PLA2G4B | c.1399-73G>C | Intron (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- KCTD15 | c.*139G>A | 3'UTR (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- LINC00552 | n.256_265del | RNA (DEL) | VAF 162/882 reads (18%) | called by pindel, varscan2
- MCTP1 | c.2436+1009C>G | Intron (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- MRNIP | chr5:179860441 C>A | 5'Flank (SNP) | VAF 104/329 reads (32%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45226872 C>G | 3'Flank (SNP) | VAF 92/657 reads (14%) | called by muse, mutect2, varscan2
- RO60 | c.-179C>T | 5'UTR (SNP) | VAF 35/238 reads (15%) | catalogued as rs1205252222; called by muse, mutect2, varscan2
- SKA2P1 | n.51A>G | RNA (SNP) | VAF 61/163 reads (37%) | called by muse, mutect2, varscan2
- TNNT2 | c.53-36C>G | Intron (SNP) | VAF 98/429 reads (23%) | catalogued as COSV52661860; called by muse, mutect2, varscan2
- VGLL3 | c.937+5548A>G | Intron (SNP) | VAF 2/12 reads (17%) | called by muse, mutect2
